Somatic mutation profile of tumor specimen 0DH731 from CCDI case PBBUJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Cerebrum; Age at diagnosis: 0.3 years (93 days).
Specimen 0DH731: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42d490f2-8617-4bfe-b9e2-e1194e97bef4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH6ZY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/231606e4-989c-4cc1-b29e-d95533821a7d

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOLR1 | c.731T>C p.F244S | Missense Mutation (SNP) | VAF 227/677 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED13L | c.5941C>T p.Q1981* | Nonsense Mutation (SNP) | VAF 72/1188 reads (6%) | called by muse, mutect2
- PUS1 | c.*23A>G | 3'UTR (SNP) | VAF 223/689 reads (32%) | called by muse, mutect2, varscan2
